TCGA case TCGA-BQ-5879 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b877d608-e4e0-4b28-9235-01dd65849cf7

Demographics
Sex at birth: female; Race: white; Age at index: 32 years; Vital status: Dead; Days to death: 697 days (1.9 years).

Diagnoses (4)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 32.5 years (11,862 days); Year of diagnosis: 2005; AJCC clinical T: T3a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 26.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 192 days; Days to treatment end: 430 days (1.2 years); Number of cycles: 6; Prescribed dose: 25; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Days to treatment start: 192 days; Days to treatment end: 430 days (1.2 years); Number of cycles: 6; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Initial disease status: Progressive Disease; Days to treatment start: 472 days (1.3 years); Days to treatment end: 493 days (1.3 years); Number of cycles: 1; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 472 days (1.3 years); Days to treatment end: 493 days (1.3 years); Number of cycles: 1; Prescribed dose: 15; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 508 days (1.4 years); Days to treatment end: 591 days (1.6 years); Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 612 days (1.7 years); Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 32.8 years (11,992 days); Days to diagnosis: 130 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 33.7 years (12,292 days); Days to diagnosis: 430 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 34.1 years (12,453 days); Days to diagnosis: 591 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 130 (post initial treatment): Progression or recurrence: Yes.
- Day 430 (post initial treatment): Progression or recurrence: Yes.
- Day 591 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 697 days (1.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Leukocytes: Normal.
- Hemoglobin: Normal.
- Platelets: Normal.
- Calcium: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79.2 kg; Height: 153 cm; BMI: 33.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BQ-5879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.3; Shortest dimension: 0.2.
  Slide TCGA-BQ-5879-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10.
  Slide TCGA-BQ-5879-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-BQ-5879-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BQ-5879-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.2; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Tobacco smoking history indicator: 4.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 2; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 3; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Previous trial closed, prescribed new medical treatment.
- Drug treatment 6: Regimen number: 4; Therapy regimen: Progression.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 697 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 697 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 130 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BQ-5879-01A-11D-1588-01): tumor purity 0.75, ploidy 1.77, whole-genome doublings 0.
